MMRF case MMRF_1854 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/fcf81ad6-734d-43a8-9803-6143cf8b8b77

Demographics
Sex at birth: female; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 52.9 years (19,326 days); ISS stage: II; Days to last known disease status: 1,066 days (2.9 years); Days to last follow up: 1,066 days (2.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 85 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 118 days; Days to treatment end: 118 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 119 days; Days to treatment end: 119 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 208 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13: M Protein 2.57 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.15 mg/dL; Immunoglobulin G 35 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 1.28 µg/mL; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.11 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.2 mmol/L; Albumin 33 g/L; Total Protein 8.2 g/dL; Glucose 5.39 mmol/L; C-Reactive Protein 0.226 mg/dL.
- Day 64 (ECOG 0): M Protein 0.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.86 mg/dL; Immunoglobulin G 7.78 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 1.17 µg/mL; Lactate Dehydrogenase 4.08 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5.29 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 4.51 mmol/L.
- Day 179 (ECOG 0): M Protein 0.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.58 mg/dL; Immunoglobulin G 9.86 g/L; Immunoglobulin A 0.66 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 1.17 µg/mL; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.39 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 47 g/L; Total Protein 7.9 g/dL; Glucose 5.67 mmol/L.
- Day 253 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.745 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.646 mg/dL; Immunoglobulin G 7.37 g/L; Immunoglobulin A 0.7 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.2 µg/mL; Lactate Dehydrogenase 3.65 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 6.6 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 4.51 mmol/L.
- Day 365 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.732 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.683 mg/dL; Immunoglobulin G 6.61 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.1 µg/mL; Lactate Dehydrogenase 3.98 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 5.8 g/dL; Glucose 4.4 mmol/L.
- Day 457: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Immunoglobulin G 6.5 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 1 µg/mL; Lactate Dehydrogenase 3.7 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 5.34 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 5.5 mmol/L.
- Day 547 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.17 mg/dL; Immunoglobulin G 6.45 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 1.13 µg/mL; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 1.02 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 5.8 g/dL; Glucose 4.35 mmol/L.
- Day 625: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.605 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.732 mg/dL; Immunoglobulin G 5.62 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 1.2 µg/mL; Lactate Dehydrogenase 4.23 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 5.78 mmol/L.
- Day 729 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 7.51 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 1.03 µg/mL; Lactate Dehydrogenase 3.7 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.46 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 4.9 mmol/L.
- Day 793: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 6.37 g/L; Immunoglobulin A 0.546 g/L; Immunoglobulin M 0.123 g/L; Lactate Dehydrogenase 9.79 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 2.69 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.1 mmol/L; Albumin 33 g/L; Total Protein 5.5 g/dL; Glucose 4.02 mmol/L.
- Day 911 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.85 mg/dL; Immunoglobulin G 6.48 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 1.23 µg/mL; Lactate Dehydrogenase 4.98 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.28 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 5.34 mmol/L.
- Day 996: Lactate Dehydrogenase 11.9 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 3.17 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 5.5 g/dL; Glucose 5.34 mmol/L.
- Day 1,066: M Protein 0 g/dL; Immunoglobulin G 6.89 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.243 g/L; Beta 2 Microglobulin 1.15 µg/mL; Lactate Dehydrogenase 10.9 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 2.12 ×10⁹/L; Absolute Neutrophil 1.18 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 5.01 mmol/L.

Other clinical attributes
- Day -13: Weight: 86 kg; Height: 163 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Multiple Myeloma; Relationship sex at birth: male.

Biospecimens (3 samples)
- Sample MMRF_1854_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1854_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
- Sample MMRF_1854_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 179 days.
